Gene-level copy-number profile of tumor specimen TCGA-HF-7134-01A from TCGA case TCGA-HF-7134, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen TCGA-HF-7134-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7caff7ee-cbf3-46be-a493-cd83b76b1dfc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HF-7134-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ccab5b2-521e-4cb5-a1bd-67b7e4542610

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,862; copy number 2: 42,886; copy number 3: 8,548; copy number 4: 5,085; copy number 5: 4; copy number 6: 137; copy number 9: 8; copy number 12: 117; copy number 15: 144; copy number 18: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HF-7134-01A-11D-2052-01): tumor purity 0.76, ploidy 2.38, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:235,773,855–235,882,493, 2 genes: AC064874.1, TMSB10P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 436 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:36,740,775–50,049,929, 293 genes, copy number 6–15 (within-gene range 1–15) (broad region; genes not listed).
- chr6:51,385,282–54,266,280, 73 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:60,281,444–60,723,898, 3 genes, copy number 5 (within-gene range 1–5): AC244258.1, GAPDHP41, AL590227.1.
- chr6:60,826,185–60,826,533, 1 gene, copy number 5: AL512427.1.
- chr6:62,460,940–65,707,226, 26 genes, copy number 18 (within-gene range 1–18): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr11:69,371,463–70,436,584, 34 genes, copy number 12: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 12: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.

Autosomal genes at a single copy (total copy number 1): 441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
